CPTAC case C3L-00540 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7ae9f40d-0dad-4328-905e-836d4ac81e34

Demographics
Sex at birth: female; Race: white; Year of birth: 1948; Vital status: Dead; Days to death: 256 days; Year of death: 2018; Cause of death: Cancer Related.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Hematopoietic system, NOS; Age at diagnosis: 69.0 years (25,217 days); Year of diagnosis: 2017; Days to last known disease status: 256 days; Progression or recurrence: no; Days to last follow up: 235 days.

Follow-up (1 entry)
- Days to follow up: 235 days; Karnofsky performance status: 90; ECOG performance status: 1.

Other clinical attributes
- Weight: 90.72 kg; Height: 157.48 cm; BMI: 36.58; Comorbidities: Hyperlipidemia.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (5 samples)
- Samples C3L-00540-51, C3L-00540-52, C3L-00540-53 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-00540-59, C3L-00540-60 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 4 days; Time between excision and freezing: 285 minutes; Method of sample procurement: Blood Draw; Diagnosis pathologically confirmed: Yes.
